Somatic mutation profile of tumor specimen MP2PRT-PATBNA-TMP1-A (aliquot MP2PRT-PATBNA-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATBNA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (734 days).
Specimen MP2PRT-PATBNA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 634964b8-8aa9-4289-a7c6-2ae13de2c312.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBNA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBNA-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a60682a9-12e2-4d4f-89e9-d223c6b243cc

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 30/495 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs145300703; called by muse, mutect2
- COL12A1 | c.7733C>T p.T2578M | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554169931; called by muse, mutect2, varscan2
- YEATS2 | c.3037G>A p.V1013I | Missense Mutation (SNP) | VAF 115/347 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs746480291; called by muse, mutect2, varscan2
- ANKRD22 | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CEMIP | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 46/488 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- NRG3 | c.1529A>C p.Y510S | Missense Mutation (SNP) | VAF 77/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTRA1 | c.1350C>T p.D450= | Silent (SNP) | VAF 54/398 reads (14%) | catalogued as rs374675648; called by muse, mutect2, varscan2
- TTN | c.10361-4197G>A | Intron (SNP) | VAF 18/245 reads (7%) | catalogued as rs199565262, COSV60193887; ClinVar: uncertain significance; called by muse, mutect2
